Somatic mutation profile of tumor specimen TCGA-WE-A8ZQ-06A (aliquot TCGA-WE-A8ZQ-06A-41D-A372-08) from TCGA case TCGA-WE-A8ZQ, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Nodular melanoma; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 52.8 years (19,303 days).
Specimen TCGA-WE-A8ZQ-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b1ba05ae-e5c9-4896-a0b5-605c8d8362fd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WE-A8ZQ-10A (Blood Derived Normal), aliquot TCGA-WE-A8ZQ-10A-01D-A375-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0ed02903-f92c-4af0-ad8a-1dc505564e96

The open-access MAF lists 199 somatic variants for this specimen: 134 protein-altering or splice-affecting, 59 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 124, Silent 59, Nonsense Mutation 7, RNA 2, Intron 1, Splice Region 1, 3'Flank 1, Frame Shift Del 1, 3'UTR 1, Translation Start Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALK | c.1202G>A p.R401Q | Missense Mutation (SNP) | VAF 19/64 reads (30%) | hotspot (GDC flag); SIFT tolerated (0.48); PolyPhen benign (0.167); catalogued as rs188859061, COSV66560684, COSV66576644; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 106/156 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ABCA12 | c.1324G>A p.E442K (on ENST00000272895 / NM_173076.3; = p.E124K on NM_015657.3) | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV55950013, COSV99791991; called by muse, mutect2, varscan2
- ABCA5 | c.4651C>T p.Q1551* | Nonsense Mutation (SNP) | VAF 57/91 reads (63%) | catalogued as rs765828096, COSV101201282; called by muse, mutect2, varscan2
- ACSM2A | c.194C>A p.P65Q | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.067); catalogued as COSV54586962; called by muse, mutect2
- ADAMTS2 | c.2505G>A p.M835I | Missense Mutation (SNP) | VAF 49/110 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as COSV99283836; called by muse, mutect2, varscan2
- ADCK1 | c.745C>T p.P249S | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53084333; called by muse, mutect2, varscan2
- ADGRF4 | c.2059G>A p.G687R | Missense Mutation (SNP) | VAF 154/262 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV99348979; called by muse, mutect2, varscan2
- ADGRV1 | c.15181G>A p.G5061R | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV101316502; called by muse, mutect2, varscan2
- ARID1A | c.2365C>T p.Q789* | Nonsense Mutation (SNP) | VAF 25/69 reads (36%) | catalogued as COSV99055332; called by muse, mutect2, varscan2
- ARSG | c.86G>A p.G29E | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV101477927; called by muse, mutect2, varscan2
- ATG2B | c.368G>T p.S123I | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1324014466, COSV100738246; called by muse, mutect2
- ATXN3 | c.196T>C p.S66P | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100515616; called by muse, mutect2, varscan2
- BMP15 | c.902G>A p.R301H | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1338075370, COSV99399536; called by muse, mutect2, varscan2
- BTNL8 | c.842G>A p.R281K (on ENST00000340184 / NM_001040462.3; = p.E324= on NM_024850.2) | Missense Mutation (SNP) | VAF 52/56 reads (93%) | SIFT tolerated (0.1); PolyPhen benign (0.206); catalogued as COSV99180578; called by muse, mutect2, varscan2
- CD226 | c.599G>A p.S200N | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.22); catalogued as rs1265415532, COSV54610925; called by muse, mutect2, varscan2
- CERCAM | c.722C>T p.P241L | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as COSV100864118; called by muse, mutect2, varscan2
- CHRNA3 | c.1507G>A p.E503K | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.033); catalogued as rs1212226077, COSV55138731; called by muse, mutect2, varscan2
- CLEC6A | c.446G>A p.W149* | Nonsense Mutation (SNP) | VAF 15/85 reads (18%) | catalogued as rs1273995378, COSV101165711; called by muse, mutect2, varscan2
- CNTN5 | c.1519G>T p.G507C | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV99681258; called by muse, mutect2, varscan2
- COL17A1 | c.1900G>A p.E634K | Missense Mutation (SNP) | VAF 59/65 reads (91%) | SIFT deleterious (0.01); PolyPhen benign (0.141); catalogued as rs755604780, COSV100793355; called by muse, mutect2, varscan2
- COL6A6 | c.3113G>A p.R1038Q | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.77); PolyPhen benign (0.033); catalogued as rs372502446; called by muse, mutect2, varscan2
- CRTC2 | c.560C>T p.T187I | Missense Mutation (SNP) | VAF 33/122 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.857); catalogued as rs1265090270, COSV100339351; called by muse, mutect2, varscan2
- CSMD3 | c.772C>T p.P258S | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV52164534; called by muse, mutect2, varscan2
- DCC | c.2386C>A p.L796I | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100503042; called by muse, mutect2, varscan2
- DLGAP2 | c.388G>C p.G130R | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.68); PolyPhen benign (0.202); catalogued as COSV101422687, COSV70099967; called by muse, mutect2, varscan2
- DMBX1 | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 54/82 reads (66%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.385); catalogued as rs142474862; called by muse, mutect2, varscan2
- DNAJB5 | c.982C>T p.R328C | Missense Mutation (SNP) | VAF 49/102 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.052); catalogued as rs1482500506, COSV56624605; called by muse, mutect2, varscan2
- DTX4 | c.365C>T p.P122L | Missense Mutation (SNP) | VAF 35/156 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as rs779827794, COSV99915940; called by muse, mutect2, varscan2
- ELFN2 | c.469G>A p.D157N | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV68746729; called by muse, mutect2, varscan2
- EMILIN3 | c.917G>A p.R306Q | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs747522209, COSV60035601; called by muse, mutect2, varscan2
- EPHB1 | c.2698C>A p.Q900K | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0.152); catalogued as COSV67675468; called by muse, mutect2, varscan2
- ESRRG | c.918G>A p.M306I | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV63169780; called by muse, mutect2, varscan2
- F8 | c.3305G>A p.G1102D | Missense Mutation (SNP) | VAF 88/93 reads (95%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as rs1557278673, COSV100811947; called by muse, mutect2, varscan2
- FAT3 | c.8195T>G p.I2732S | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.371); catalogued as COSV53119106, COSV99970925; called by muse, mutect2, varscan2
- FBL | c.592C>T p.R198C | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.825); catalogued as rs377432606; called by muse, mutect2, varscan2
- FLNC | c.7310G>A p.R2437Q | Missense Mutation (SNP) | VAF 51/154 reads (33%) | SIFT tolerated (0.58); PolyPhen benign (0.148); catalogued as rs201762568, COSV57955653; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FOLH1 | c.832G>T p.A278S | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.025); catalogued as COSV99923933; called by muse, mutect2, varscan2
- GALNT2 | c.1277T>G p.F426C | Missense Mutation (SNP) | VAF 54/169 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs779172012, COSV100795886; called by muse, mutect2, varscan2
- GRM7 | c.553G>C p.E185Q | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV100738599, COSV63130639, COSV63139535; called by muse, mutect2, varscan2
- HKDC1 | c.2506G>T p.G836C | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100664772; called by muse, mutect2, varscan2
- HMCN1 | c.12319C>T p.P4107S | Missense Mutation (SNP) | VAF 40/245 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0.072); catalogued as COSV54923865, COSV99635547; called by muse, mutect2, varscan2
- HMGCLL1 | c.463C>T p.L155F | Missense Mutation (SNP) | VAF 30/167 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.121); catalogued as COSV99233207; called by muse, mutect2, varscan2
- HNRNPA2B1 | c.1025G>A p.G342E (on ENST00000354667 / NM_031243.3; = p.G330E on NM_002137.4) | Missense Mutation (SNP) | VAF 206/317 reads (65%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.988); catalogued as COSV100668451; called by muse, mutect2, varscan2
- HNRNPA2B1 | c.1024G>A p.G342R (on ENST00000354667 / NM_031243.3; = p.G330R on NM_002137.4) | Missense Mutation (SNP) | VAF 203/314 reads (65%) | SIFT tolerated, low confidence (0.43); PolyPhen probably damaging (0.991); catalogued as COSV100668260; called by muse, mutect2, varscan2
- IFNA14 | c.551G>A p.R184K | Missense Mutation (SNP) | VAF 20/168 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV101207354; called by muse, mutect2
- IGHV3-53 | c.83G>A p.G28E | Missense Mutation (SNP) | VAF 151/185 reads (82%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.826); catalogued as rs1166403197; called by muse, mutect2, varscan2
- IGSF9B | c.2740C>T p.P914S | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.264); catalogued as COSV100318412; called by muse, mutect2, varscan2
- INPPL1 | c.2399C>T p.S800L | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.095); catalogued as COSV99996644; called by muse, mutect2
- IPO7 | c.2494C>T p.H832Y | Missense Mutation (SNP) | VAF 67/126 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1202142948, COSV101121786; called by mutect2, varscan2
- IQCN | c.626C>T p.P209L | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.908); catalogued as COSV101149022; called by muse, mutect2, varscan2
- IQCN | c.625C>T p.P209S | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.857); catalogued as COSV66579501; called by muse, mutect2, varscan2
- IRF2 | c.40G>T p.E14* | Nonsense Mutation (SNP) | VAF 11/77 reads (14%) | catalogued as COSV101165908; called by muse, mutect2, varscan2
- ITGA5 | c.2035C>T p.H679Y | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.362); catalogued as COSV99516948; called by muse, mutect2, varscan2
- ITGA8 | c.2291G>A p.S764N | Missense Mutation (SNP) | VAF 31/36 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1307446469, COSV100958872, COSV100959732; called by muse, mutect2, varscan2
- KEL | c.731C>T p.A244V | Missense Mutation (SNP) | VAF 90/304 reads (30%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.542); catalogued as COSV100787294; called by muse, mutect2, varscan2
- KIAA1586 | c.1399A>G p.K467E | Missense Mutation (SNP) | VAF 47/83 reads (57%) | SIFT tolerated (0.37); PolyPhen benign (0.179); catalogued as rs1301377865, COSV100875396; called by muse, mutect2, varscan2
- KIF1B | c.5071C>T p.P1691S (on ENST00000377086 / NM_001365952.1; = p.P1645S on NM_015074.3) | Missense Mutation (SNP) | VAF 48/167 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99824170; called by muse, mutect2, varscan2
- KRTAP5-10 | c.257C>T p.S86F | Missense Mutation (SNP) | VAF 72/188 reads (38%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.394); catalogued as rs749141269, COSV64794446; called by muse, mutect2, varscan2
- LAMA1 | c.8317C>T p.L2773F | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as rs144592838; called by muse, mutect2, varscan2
- LAMA5 | c.1961C>T p.P654L | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.777); catalogued as rs917054745, COSV99442249; called by muse, mutect2, varscan2
- LAMC3 | c.739G>A p.D247N | Missense Mutation (SNP) | VAF 80/131 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs200998540, COSV100735999; called by muse, mutect2, varscan2
- LBP | c.61C>T p.P21S | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT tolerated (0.53); PolyPhen benign (0.017); catalogued as rs1471810815, COSV99461346; called by muse, mutect2, varscan2
- LCE1B | c.212G>A p.G71E | Missense Mutation (SNP) | VAF 36/205 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100780316; called by muse, mutect2, varscan2
- LGR6 | c.2009C>T p.S670F (on ENST00000367278 / NM_001017403.1; = p.S618F on NM_021636.3) | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV55151162; called by muse, mutect2
- LIMS2 | c.196C>A p.H66N (on ENST00000355119 / NM_001161403.3; = p.H90N on NM_017980.4) | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.096); catalogued as COSV99760765; called by muse, mutect2, varscan2
- LIPC | c.530C>T p.A177V | Missense Mutation (SNP) | VAF 37/180 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100134866; called by muse, mutect2, varscan2
- LRP1B | c.10042G>A p.E3348K | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101260931; called by muse, mutect2, varscan2
- MEFV | c.554G>A p.G185E | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious (0.03); PolyPhen benign (0.045); catalogued as rs1221398722, COSV99561290; called by muse, mutect2, varscan2
- MRTFB | c.67C>T p.P23S | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100565600; called by muse, mutect2, varscan2
- MUC16 | c.34456G>A p.E11486K | Missense Mutation (SNP) | VAF 60/104 reads (58%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.031); catalogued as rs1436844354, COSV67472388; called by muse, mutect2, varscan2
- MUC16 | c.29032C>T p.P9678S | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.031); catalogued as rs779311323, COSV67492941; called by muse, mutect2, varscan2
- MUC16 | c.11772G>A p.W3924* | Nonsense Mutation (SNP) | VAF 9/17 reads (53%) | catalogued as COSV67455226; called by muse, mutect2, varscan2
- NAA11 | c.273G>A p.M91I | Missense Mutation (SNP) | VAF 59/95 reads (62%) | SIFT deleterious (0); PolyPhen benign (0.047); catalogued as COSV54513859; called by muse, mutect2, varscan2
- NADSYN1 | c.7C>T p.R3W | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs756459302, COSV100035033; called by muse, mutect2, varscan2
- NKTR | c.1679G>A p.R560Q | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs778115792, COSV99236351; called by muse, mutect2, varscan2
- NLRP2 | c.1421G>A p.G474E | Missense Mutation (SNP) | VAF 46/82 reads (56%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.874); catalogued as rs1486674500, COSV99672647; called by muse, mutect2, varscan2
- NOL9 | c.1612C>T p.P538S | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.11); catalogued as COSV100891526, COSV66625737; called by muse, mutect2, varscan2
- NPY2R | c.348G>A p.W116* | Nonsense Mutation (SNP) | VAF 15/58 reads (26%) | catalogued as COSV61529560; called by muse, mutect2, varscan2
- OR13G1 | c.739C>T p.L247F | Missense Mutation (SNP) | VAF 28/181 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.192); catalogued as COSV62943585, COSV62945395; called by muse, mutect2, varscan2
- PCLO | c.13382G>A p.R4461Q | Missense Mutation (SNP) | VAF 32/134 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.985); catalogued as rs762172311, COSV61615219; called by muse, mutect2, varscan2
- PCSK2 | c.239G>A p.R80K | Missense Mutation (SNP) | VAF 42/276 reads (15%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV99360710; called by muse, mutect2, varscan2
- PLG | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 56/56 reads (100%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV99805112; called by muse, mutect2, varscan2
- PM20D1 | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV100900249; called by muse, mutect2, varscan2
- PPFIA2 | c.3057G>A p.M1019I | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as COSV100335233; called by muse, mutect2, varscan2
- PRKAB1 | c.377A>G p.K126R | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); catalogued as COSV99982468; called by muse, mutect2, varscan2
- PRR12 | c.1679C>T p.S560F (on ENST00000615927; = p.S1381F on NM_020719.3) | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101330790; called by muse, mutect2, varscan2
- PRUNE1 | c.913C>T p.H305Y | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT tolerated (0.47); PolyPhen benign (0.097); catalogued as COSV99639953; called by muse, mutect2, varscan2
- PSAT1 | c.355G>T p.G119W | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.614); catalogued as COSV100716711; called by mutect2, varscan2
- PTEN | c.138del p.Y46* | Frame Shift Del (DEL) | VAF 31/45 reads (69%) | catalogued as CM142090, CM165876, COSV64290071; called by mutect2, pindel, varscan2
- RBFOX1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 13/35 reads (37%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV101384631; called by muse, mutect2, varscan2
- RNF148 | c.97A>G p.N33D | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV100411756; called by muse, mutect2, varscan2
- ROS1 | c.4423C>G p.L1475V | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT tolerated (0.41); PolyPhen benign (0.073); catalogued as COSV100877702; called by muse, mutect2
- RP1L1 | c.3001G>A p.E1001K | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0.113); catalogued as COSV101223617; called by muse, mutect2, varscan2
- RPL28 | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.383); catalogued as COSV100689477; called by muse, mutect2, varscan2
- RPRD2 | c.3706C>T p.P1236S | Missense Mutation (SNP) | VAF 27/168 reads (16%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as COSV100955370; called by muse, mutect2, varscan2
- RPS6KC1 | c.3159T>G p.H1053Q | Missense Mutation (SNP) | VAF 76/135 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100874094; called by muse, mutect2, varscan2
- RYR1 | c.2156A>G p.H719R | Missense Mutation (SNP) | VAF 38/158 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100615360, COSV100616999; called by muse, mutect2, varscan2
- SAGE1 | c.1129G>A p.D377N | Missense Mutation (SNP) | VAF 123/128 reads (96%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.497); catalogued as COSV100187909; called by muse, mutect2, varscan2
- SAMD9L | c.1360G>A p.G454R | Missense Mutation (SNP) | VAF 148/228 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100561138; called by muse, mutect2, varscan2
- SLC17A1 | c.1378A>C p.K460Q | Missense Mutation (SNP) | VAF 41/195 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.495); catalogued as COSV99766146; called by muse, mutect2, varscan2
- SLC44A2 | c.325C>T p.P109S | Missense Mutation (SNP) | VAF 50/127 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.272); catalogued as COSV100213460; called by muse, mutect2, varscan2
- SLC4A1AP | c.1127G>C p.G376A | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV100389647; called by muse, mutect2, varscan2
- SLF2 | c.941G>C p.R314T | Missense Mutation (SNP) | VAF 68/126 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV99489734; called by muse, mutect2, varscan2
- SLIT2 | c.792G>A p.M264I | Missense Mutation (SNP) | VAF 66/181 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV99883761, COSV99887190; called by muse, mutect2, varscan2
- STXBP5L | c.1384G>A p.E462K | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99876451; called by muse, mutect2, varscan2
- SYNE1 | c.21817G>A p.D7273N (on ENST00000367255 / NM_182961.4; = p.D7202N on NM_033071.3) | Missense Mutation (SNP) | VAF 95/105 reads (90%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.848); catalogued as COSV99578382; called by muse, mutect2, varscan2
- TAOK1 | c.2753C>T p.P918L | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); catalogued as COSV55588486; called by muse, mutect2, varscan2
- TECPR1 | c.3085C>T p.P1029S | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65783172; called by muse, mutect2, varscan2
- TENM1 | c.3642T>A p.N1214K | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV100950939; called by muse, mutect2, varscan2
- TENM1 | c.3641A>G p.N1214S | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.341); catalogued as COSV100950940; called by muse, mutect2, varscan2
- TESPA1 | c.538C>T p.R180W (on ENST00000316577 / NM_001098815.3; = p.R42W on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 82/128 reads (64%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs767900906, COSV57258476; called by muse, mutect2, varscan2
- TEX15 | c.5402C>T p.S1801F (on ENST00000256246; = p.S2184F on NM_001350162.2) | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as COSV56345421, COSV56355535; called by muse, mutect2, varscan2
- TLN2 | c.2366G>A p.R789Q | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.296); catalogued as rs768628001, COSV100170028; called by muse, mutect2, varscan2
- TTC17 | c.1087A>C p.K363Q | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.981); catalogued as COSV99236016; called by muse, mutect2, varscan2
- TTC23 | c.115C>T p.Q39* | Nonsense Mutation (SNP) | VAF 21/90 reads (23%) | catalogued as rs749495305, COSV100019270; called by muse, mutect2, varscan2
- TTN | c.46046A>G p.K15349R (on ENST00000591111; = p.K7925R on NM_003319.4) | Missense Mutation (SNP) | VAF 20/58 reads (34%) | PolyPhen probably damaging (0.994); catalogued as COSV100629670; called by muse, mutect2, varscan2
- TTN | c.25439C>T p.S8480L (on ENST00000591111; = p.S7553L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 83/139 reads (60%) | PolyPhen benign (0); catalogued as COSV100629672; called by muse, mutect2, varscan2
- TTN | c.4775A>G p.N1592S (on ENST00000591111; = p.N1546S on NM_003319.4) | Missense Mutation (SNP) | VAF 85/158 reads (54%) | PolyPhen probably damaging (0.994); catalogued as COSV100629680; called by muse, mutect2, varscan2
- UBE4B | c.2239C>T p.P747S (on ENST00000343090 / NM_001105562.3; = p.P618S on NM_006048.5) | Missense Mutation (SNP) | VAF 36/150 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.129); catalogued as COSV53527473; called by muse, mutect2, varscan2
- UBE4B | c.2240C>T p.P747L (on ENST00000343090 / NM_001105562.3; = p.P618L on NM_006048.5) | Missense Mutation (SNP) | VAF 36/149 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV99477616; called by muse, mutect2, varscan2
- UGT2B15 | c.801T>A p.F267L | Missense Mutation (SNP) | VAF 70/263 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); catalogued as COSV100592456; called by muse, mutect2, varscan2
- USP26 | c.1100C>T p.A367V | Missense Mutation (SNP) | VAF 94/99 reads (95%) | SIFT tolerated (0.28); PolyPhen benign (0.232); catalogued as rs1195913364, COSV100896760, COSV100896763; called by muse, mutect2, varscan2
- VIT | c.1624G>A p.E542K (on ENST00000389975 / NM_001177969.1; = p.E557K on NM_053276.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776323615, COSV64895242; called by muse, mutect2, varscan2
- VWA2 | c.527G>A p.R176K | Missense Mutation (SNP) | VAF 27/33 reads (82%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV100073379, COSV100073967; called by muse, mutect2, varscan2
- VWA3B | c.543G>A p.R181= | Splice Region (SNP) | VAF 22/36 reads (61%) | catalogued as COSV68243230; called by muse, mutect2, varscan2
- XYLT1 | c.808C>T p.R270C | Missense Mutation (SNP) | VAF 64/145 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs758139451, COSV99763302; called by muse, mutect2, varscan2
- ZDHHC2 | c.970C>T p.P324S | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV50497597; called by muse, mutect2
- ZNF304 | c.1153C>T p.H385Y | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as rs1231391411, COSV56583247; called by muse, mutect2, varscan2
- ZNF334 | c.1022G>A p.R341K | Missense Mutation (SNP) | VAF 126/327 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.15); catalogued as rs763437357, COSV100749202; called by muse, mutect2, varscan2
- ZNF789 | c.1079A>G p.Q360R | Missense Mutation (SNP) | VAF 30/158 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.05); catalogued as COSV100508004; called by muse, mutect2, varscan2
- IGHE | c.1216C>G p.R406G | Missense Mutation (SNP) | VAF 38/71 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.324); called by muse, mutect2, varscan2
- PRAMEF15 | c.754C>T p.P252S | Missense Mutation (SNP) | VAF 82/626 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.025); called by muse, varscan2
- TJP3 | c.1649G>A p.S550N | Missense Mutation (SNP) | VAF 2/8 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.017); called by muse, mutect2
- ABCC3 | c.2382C>T p.I794= | Silent (SNP) | VAF 48/84 reads (57%) | catalogued as rs149910028; ClinVar: likely benign; called by muse, mutect2, varscan2
- ACHE | c.1461G>A p.G487= | Silent (SNP) | VAF 11/71 reads (15%) | catalogued as rs1448498747, COSV53816731, COSV99574575; called by muse, mutect2, varscan2
- ACP7 | c.576C>T p.P192= | Silent (SNP) | VAF 31/106 reads (29%) | catalogued as rs775669799, COSV100488611; called by muse, mutect2, varscan2
- ACSM2A | c.807C>T p.I269= (on ENST00000219054; = p.I190= on NM_001308169.2) | Silent (SNP) | VAF 121/250 reads (48%) | catalogued as rs767603255, COSV99525707; called by muse, mutect2, varscan2
- ANKRD39 | c.192C>T p.G64= | Silent (SNP) | VAF 55/167 reads (33%) | catalogued as COSV101135748; called by muse, mutect2, varscan2
- ATF6B | c.1668C>T p.P556= | Silent (SNP) | VAF 21/97 reads (22%) | catalogued as COSV100916853; called by muse, mutect2, varscan2
- CACNA2D3 | c.1065G>T p.T355= | Silent (SNP) | VAF 12/25 reads (48%) | catalogued as rs376273944, COSV99877039; called by muse, mutect2, varscan2
- CCDC77 | c.1095G>A p.E365= | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as rs140718277, COSV99520076; called by muse, mutect2, varscan2
- CDHR2 | c.3498C>T p.V1166= | Silent (SNP) | VAF 58/120 reads (48%) | catalogued as COSV99992182; called by muse, mutect2, varscan2
- CDON | c.3774C>A p.P1258= (on ENST00000392693 / NM_001243597.2; = p.P1235= on NM_016952.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 23/101 reads (23%) | catalogued as COSV55003576, COSV99701979; called by muse, mutect2, varscan2
- CLEC18A | c.27C>T p.G9= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as rs1429688483; called by mutect2, varscan2
- CLRN3 | c.378G>A p.P126= | Silent (SNP) | VAF 39/47 reads (83%) | catalogued as rs758440336, COSV100899791; called by muse, mutect2, varscan2
- CPLX2 | c.51G>A p.G17= | Silent (SNP) | VAF 22/39 reads (56%) | catalogued as COSV64001710; called by muse, mutect2, varscan2
- DIO3 | c.789C>T p.V263= | Silent (SNP) | VAF 21/88 reads (24%) | catalogued as COSV100832278; called by muse, mutect2, varscan2
- DNASE1L2 | c.516G>A p.A172= | Silent (SNP) | VAF 20/38 reads (53%) | catalogued as rs1490294871, COSV100066102; called by muse, mutect2, varscan2
- DRAXIN | c.222G>A p.Q74= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV99610951; called by muse, mutect2, varscan2
- FBN3 | c.7380C>T p.L2460= | Silent (SNP) | VAF 47/80 reads (59%) | catalogued as COSV99561828; called by muse, mutect2, varscan2
- FBXL20 | c.1305C>T p.I435= | Silent (SNP) | VAF 61/99 reads (62%) | catalogued as COSV99234735; called by muse, mutect2, varscan2
- GAD2 | c.378C>T p.F126= | Silent (SNP) | VAF 27/57 reads (47%) | catalogued as rs1387953693, COSV99393310; called by muse, mutect2, varscan2
- GIMAP1 | c.117G>A p.G39= | Silent (SNP) | VAF 64/323 reads (20%) | catalogued as COSV56187521; called by muse, mutect2, varscan2
- GJB4 | c.264A>C p.S88= | Silent (SNP) | VAF 28/34 reads (82%) | catalogued as COSV100258702; called by muse, mutect2, varscan2
- HMGB4 | c.297C>T p.S99= | Silent (SNP) | VAF 37/94 reads (39%) | catalogued as COSV99595209; called by muse, mutect2, varscan2
- KCNJ15 | c.573G>C p.G191= | Silent (SNP) | VAF 18/67 reads (27%) | catalogued as COSV100154415; called by muse, mutect2, varscan2
- KMT2D | c.3777C>T p.L1259= | Silent (SNP) | VAF 43/155 reads (28%) | catalogued as COSV99985696; called by muse, mutect2, varscan2
- KRT16 | c.1269C>T p.G423= | Silent (SNP) | VAF 29/114 reads (25%) | catalogued as rs761807016, COSV100053042; called by muse, mutect2, varscan2
- LCE5A | c.90C>A p.P30= | Silent (SNP) | VAF 44/121 reads (36%) | catalogued as COSV57499960; called by muse, mutect2, varscan2
- LRFN5 | c.1725G>A p.G575= | Silent (SNP) | VAF 25/86 reads (29%) | catalogued as COSV53272959, COSV99985432; called by muse, mutect2, varscan2
- MMP19 | c.483C>T p.R161= | Silent (SNP) | VAF 11/99 reads (11%) | catalogued as COSV100491264; called by muse, mutect2, varscan2
- NRG1 | c.261G>A p.R87= (on ENST00000523534; = p.R234= on NM_013962.2) | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as rs768991016, COSV101585091; called by muse, mutect2, varscan2
- OR14C36 | c.303C>T p.L101= | Silent (SNP) | VAF 37/92 reads (40%) | catalogued as rs763648705, COSV58601221; called by muse, mutect2, varscan2
- OR6C2 | c.39G>A p.L13= | Silent (SNP) | VAF 64/93 reads (69%) | catalogued as rs1487847781, COSV100498759; called by muse, mutect2, varscan2
- OR8D1 | c.891G>A p.V297= | Silent (SNP) | VAF 41/120 reads (34%) | catalogued as COSV63441668; called by muse, mutect2, varscan2
- P3H3 | c.942C>T p.F314= | Silent (SNP) | VAF 21/51 reads (41%) | catalogued as COSV99301682; called by muse, mutect2, varscan2
- PABPC1 | c.375C>T p.I125= | Silent (SNP) | VAF 31/193 reads (16%) | catalogued as COSV100589865; called by muse, mutect2, varscan2
- PCDH15 | c.5037C>T p.V1679= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as COSV100905714; called by muse, mutect2
- PDCD6IP | c.574C>T p.L192= | Silent (SNP) | VAF 44/152 reads (29%) | catalogued as rs1393546923, COSV100219152; called by muse, mutect2, varscan2
- PDGFRA | c.1845A>G p.L615= | Silent (SNP) | VAF 35/91 reads (38%) | catalogued as COSV99957625; called by muse, mutect2, varscan2
- PLXNA1 | c.4653C>T p.A1551= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as rs749442884, COSV99304087; called by muse, mutect2, varscan2
- PLXNA4 | c.1638G>A p.K546= | Silent (SNP) | VAF 16/85 reads (19%) | catalogued as COSV100327054; called by muse, mutect2, varscan2
- PRPF4 | c.574T>C p.L192= (on ENST00000374198 / NM_001322267.2; = p.L193= on NM_004697.5) | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as COSV100950772; called by muse, mutect2, varscan2
- PRR5L | c.543C>T p.S181= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as COSV100287385; called by muse, mutect2, varscan2
- PTPRS | c.3660C>T p.F1220= | Silent (SNP) | VAF 35/129 reads (27%) | catalogued as COSV99512404; called by muse, mutect2, varscan2
- PYGB | c.1987C>T p.L663= | Silent (SNP) | VAF 39/183 reads (21%) | catalogued as rs199748264, COSV99405454; called by muse, mutect2, varscan2
- QRICH1 | c.2226C>T p.V742= | Silent (SNP) | VAF 19/85 reads (22%) | catalogued as COSV100455181; called by muse, mutect2, varscan2
- RHBDF2 | c.2517C>T p.F839= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as rs1393814884, COSV51684035; called by muse, mutect2, varscan2
- SIGLEC10 | c.2043C>T p.A681= | Silent (SNP) | VAF 63/95 reads (66%) | catalogued as rs956542644, COSV100219448; called by muse, mutect2, varscan2
- SLC30A8 | c.120G>A p.E40= | Silent (SNP) | VAF 30/117 reads (26%) | catalogued as COSV69967917; called by muse, mutect2, varscan2
- SLC35F1 | c.1092C>T p.P364= | Silent (SNP) | VAF 42/96 reads (44%) | catalogued as COSV100838055, COSV100838150; called by muse, mutect2, varscan2
- SMARCD3 | c.894C>T p.D298= (on ENST00000262188 / NM_001003801.2; = p.D285= on NM_003078.4) | Silent (SNP) | VAF 30/55 reads (55%) | catalogued as COSV99223334; called by muse, mutect2, varscan2
- SMG5 | c.2436C>T p.F812= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as COSV62436961, COSV62437646; called by muse, mutect2, varscan2
- STK32A | c.549C>G p.T183= | Silent (SNP) | VAF 17/104 reads (16%) | catalogued as COSV100097459, COSV100097712; called by muse, mutect2, varscan2
- TBXAS1 | c.1440C>T p.L480= | Silent (SNP) | VAF 135/194 reads (70%) | catalogued as rs1190888588, COSV54953644; called by muse, mutect2, varscan2
- TMEM132A | c.558G>A p.V186= | Silent (SNP) | VAF 36/112 reads (32%) | catalogued as rs774586914, COSV99137110; called by muse, mutect2, varscan2
- TMEM184A | c.798C>T p.F266= | Silent (SNP) | VAF 70/114 reads (61%) | catalogued as COSV99868809; called by muse, mutect2, varscan2
- TMEM215 | c.378G>A p.Q126= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as COSV100713260; called by muse, mutect2, varscan2
- TTN | c.20622G>A p.V6874= (on ENST00000591111; = p.V5947= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as rs1553912562, COSV100629677; ClinVar: likely benign; called by muse, mutect2, varscan2
- USP19 | c.553C>T p.L185= | Silent (SNP) | VAF 31/53 reads (58%) | catalogued as COSV100026489; called by muse, mutect2, varscan2
- ZMYM6 | c.1935C>T p.N645= | Silent (SNP) | VAF 28/105 reads (27%) | catalogued as COSV100593330; called by muse, mutect2, varscan2
- ZNF764 | c.345G>A p.R115= | Silent (SNP) | VAF 23/99 reads (23%) | catalogued as COSV53222083; called by muse, mutect2, varscan2
- JAKMIP1 | chr4:6049846 C>T | 3'Flank (SNP) | VAF 44/69 reads (64%) | catalogued as rs1287204488, COSV51521952, COSV99290778; called by muse, mutect2, varscan2
- KCNC2 | c.*1948G>T | 3'UTR (SNP) | VAF 9/45 reads (20%) | catalogued as COSV100129879; called by muse, mutect2, varscan2
- Metazoa_SRP | chr17:18610165 C>T | 5'Flank (SNP) | VAF 54/310 reads (17%) | catalogued as rs766517978; called by muse, mutect2, varscan2
- NFASC | c.2471-1357G>A | Intron (SNP) | VAF 22/56 reads (39%) | catalogued as rs1355583945, COSV100365645; called by muse, mutect2, varscan2
- RPL23AP42 | n.422C>T | RNA (SNP) | VAF 40/150 reads (27%) | called by muse, mutect2, varscan2
- UBTFL2 | n.213A>G | RNA (SNP) | VAF 26/209 reads (12%) | catalogued as rs1020367769; called by muse, mutect2, varscan2
